Somatic mutation profile of tumor specimen MP2PRT-PAVLRL-TMP1-A (aliquot MP2PRT-PAVLRL-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVLRL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,541 days).
Specimen MP2PRT-PAVLRL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24b609b9-a623-4d68-bd48-ab02b36376bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVLRL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVLRL-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddb69e38-6208-4a48-88f7-75d48a207ef8

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HLA-DQA2 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1349839206, COSV66566417; called by muse, mutect2
- MUC3A | c.8939G>C p.C2980S | Missense Mutation (SNP) | VAF 90/877 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs755346651, COSV100114375; called by muse, mutect2
- NALCN | c.3572C>T p.P1191L | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV51940911; called by muse, mutect2, varscan2
- PLXNB2 | c.5365G>A p.V1789M | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763150093, COSV63782087; called by muse, mutect2, varscan2
- VIPR2 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs143947210; called by muse, mutect2, varscan2
- VWF | c.4613C>T p.T1538M | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs377512022; called by muse, mutect2
- ATRX | c.5009dup p.R1671Efs*14 | Frame Shift Ins (INS) | VAF 100/190 reads (53%) | called by mutect2, pindel, varscan2
- MYO18B | c.5769G>T p.Q1923H | Missense Mutation (SNP) | VAF 104/325 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PRDM15 | c.157C>G p.H53D | Missense Mutation (SNP) | VAF 56/348 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNGTT | c.1532A>G p.D511G | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- UNC80 | c.6601C>T p.P2201S | Missense Mutation (SNP) | VAF 77/398 reads (19%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- WLS | c.199G>T p.G67* | Nonsense Mutation (SNP) | VAF 15/442 reads (3%) | called by muse, mutect2
- CACNA2D2 | c.42C>G p.G14= | Silent (SNP) | VAF 81/399 reads (20%) | called by muse, mutect2, varscan2
- CALCR | c.504G>A p.G168= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as COSV64005671; called by muse, mutect2, varscan2
- CNNM1 | c.2643G>A p.T881= | Silent (SNP) | VAF 29/336 reads (9%) | catalogued as rs772338484; called by muse, mutect2
- ELANE | c.165C>T p.C55= | Silent (SNP) | VAF 77/499 reads (15%) | catalogued as rs765808422, COSV52256540; called by muse, mutect2, varscan2
- FUT3 | c.876C>T p.H292= | Silent (SNP) | VAF 93/492 reads (19%) | catalogued as rs773934140; called by muse, varscan2
- DST | c.4297-2879A>G | Intron (SNP) | VAF 51/307 reads (17%) | catalogued as rs767640998; called by muse, mutect2, varscan2
